Gene-level copy-number profile of specimen HCM-CSHL-0382-C19-85N from HCMI case HCM-CSHL-0382-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 68.0 years (24,847 days).
Specimen HCM-CSHL-0382-C19-85N: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 9cd7df27-95d7-4253-9972-66bd89b4c6aa.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0382-C19-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,231 have no estimate.
https://portal.gdc.cancer.gov/files/5338b16d-360e-4533-b6d7-1488f36ebbe0

Most common (modal) total copy number across autosomal genes: 5 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 623; copy number 2: 317; copy number 3: 15,488; copy number 4: 16,647; copy number 5: 18,549; copy number 6: 2,965; copy number 7: 2,308; copy number 8: 50; copy number 9: 1,419; copy number 12: 4; copy number 16: 17; copy number 20: 1; copy number 22: 1; copy number 29: 1.

Homozygous deletions (total copy number 0; autosomes only): 2 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr20:15,021,553–15,022,958, 2 genes (within-gene range 0–3): RNU6-1159P, RNU6-115P.

Amplified relative to the modal value (total copy number ≥ 11, i.e. more than twice the modal value of 5; autosomes only): 24 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:97,142,161–97,283,217, 1 gene, copy number 22: MMS22L.
- chr6:106,360,717–107,133,170, 17 genes, copy number 16: CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P.
- chr6:109,690,609–109,878,098, 1 gene, copy number 20 (within-gene range 5–20): FIG4.
- chr15:84,186,752–84,256,014, 5 genes, copy number 12–29: CSPG4P11, GOLGA2P7, RN7SL331P, GOLGA6L4, UBE2Q2P8.

Autosomal genes at a single copy (total copy number 1): 623. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
